Somatic mutation profile of tumor specimen MMRF_1274_1_BM_CD138pos (aliquot MMRF_1274_1_BM_CD138pos_T2_TSE61_K03772) from MMRF case MMRF_1274, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 41.0 years (14,963 days).
Specimen MMRF_1274_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85d6f4e1-97a2-41ba-bc09-a7a262715834.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1274_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1274_1_PB_Whole_C1_TSE61_K03773; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03218298-441f-4118-92ad-13bf65e6b823

The open-access MAF lists 83 somatic variants for this specimen: 30 protein-altering or splice-affecting, 18 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 20, Silent 18, Intron 4, Nonsense Mutation 4, 5'Flank 4, 5'UTR 3, 3'Flank 3, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 44/126 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.5333G>A p.R1778H | Missense Mutation (SNP) | VAF 169/497 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs147558402; called by muse, mutect2, varscan2
- ARID3C | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 159/245 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52408877; called by muse, mutect2
- CTXN3 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206628560, COSV65218226; called by muse, mutect2, varscan2
- DOCK4 | c.1501_1503del p.K501del | In Frame Del (DEL) | VAF 36/108 reads (33%) | catalogued as rs998324528; called by pindel, varscan2
- GPX6 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1188213920, COSV62656952; called by muse, mutect2, varscan2
- GRM5 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 126/289 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59604517; called by muse, mutect2, varscan2
- RB1 | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 39/43 reads (91%) | catalogued as CM1312466, COSV57321229; called by muse, mutect2, varscan2
- SYNE1 | c.12946G>C p.E4316Q (on ENST00000367255 / NM_182961.4; = p.E4245Q on NM_033071.3) | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.296); catalogued as COSV54947405; called by muse, mutect2, varscan2
- ZNF506 | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.489); catalogued as COSV71354451; called by muse, mutect2, varscan2
- ADORA2A | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- BICC1 | c.538dup p.S180Kfs*19 | Frame Shift Ins (INS) | VAF 40/97 reads (41%) | called by mutect2, pindel, varscan2
- DAO | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FAM171A1 | c.2479C>T p.Q827* | Nonsense Mutation (SNP) | VAF 45/81 reads (56%) | called by muse, mutect2, varscan2
- GMIP | c.1883A>G p.Q628R | Missense Mutation (SNP) | VAF 186/302 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- HECW1 | c.4810G>T p.G1604* | Nonsense Mutation (SNP) | VAF 79/261 reads (30%) | called by muse, mutect2, varscan2
- MAGI1 | c.326A>C p.N109T | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PCDH19 | c.162C>A p.D54E | Missense Mutation (SNP) | VAF 100/109 reads (92%) | SIFT tolerated (0.6); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- PDIA4 | c.555_556del p.N186Lfs*2 | Frame Shift Del (DEL) | VAF 82/159 reads (52%) | called by pindel, varscan2
- RANBP2 | c.5544A>C p.K1848N | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.044); called by muse, mutect2
- RASSF6 | c.845T>C p.I282T (on ENST00000342081 / NM_201431.2; = p.I250T on NM_177532.5) | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- SETX | c.7671T>G p.D2557E | Missense Mutation (SNP) | VAF 123/393 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC22A12 | c.1557G>C p.Q519H | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- SRCAP | c.9476C>G p.P3159R | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- TGM1 | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); called by muse, varscan2
- THBS1 | c.2968G>C p.V990L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TNXB | c.5474C>A p.P1825Q (on ENST00000647633; = p.P1578Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XPR1 | c.1018A>G p.S340G | Missense Mutation (SNP) | VAF 131/215 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZDHHC19 | c.773A>T p.K258M | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZFHX4 | c.4825G>T p.E1609* | Nonsense Mutation (SNP) | VAF 28/29 reads (97%) | called by muse, mutect2, varscan2
- DMBT1 | c.7551C>T p.S2517= (on ENST00000338354 / NM_001377530.1; = p.S1760= on NM_004406.3) | Silent (SNP) | VAF 95/200 reads (48%) | called by muse, mutect2, varscan2
- DPYD | c.1623G>A p.K541= | Silent (SNP) | VAF 48/101 reads (48%) | called by muse, mutect2, varscan2
- IFT122 | c.2832C>T p.H944= (on ENST00000348417 / NM_052989.3; = p.H885= on NM_018262.4) | Silent (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- IL12RB1 | c.1047C>T p.V349= | Silent (SNP) | VAF 142/234 reads (61%) | catalogued as rs1383114026, COSV59095894; called by muse, mutect2, varscan2
- KLK1 | c.10C>T p.L4= | Silent (SNP) | VAF 101/145 reads (70%) | catalogued as COSV56826807; called by muse, mutect2, varscan2
- LIN28B | c.165C>T p.P55= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100558532; called by muse, mutect2, varscan2
- LURAP1L | c.441C>T p.G147= | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- MARK2 | c.1164C>T p.A388= | Silent (SNP) | VAF 98/195 reads (50%) | called by muse, mutect2, varscan2
- NLRP4 | c.828C>G p.L276= | Silent (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- OR2G3 | c.111G>A p.L37= | Silent (SNP) | VAF 16/354 reads (5%) | catalogued as rs1160528664; called by muse, mutect2
- PRAM1 | c.1125C>T p.F375= | Silent (SNP) | VAF 67/209 reads (32%) | catalogued as rs749944481, COSV55312020; called by muse, mutect2, varscan2
- PRKX | c.141G>A p.Q47= | Silent (SNP) | VAF 9/10 reads (90%) | called by muse, mutect2
- PRMT5 | c.1872T>A p.A624= | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- RAG1 | c.2010G>A p.T670= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs769576393, COSV55028721; called by muse, mutect2, varscan2
- SPR | c.768G>A p.V256= | Silent (SNP) | VAF 54/194 reads (28%) | catalogued as rs1171318027; called by muse, mutect2, varscan2
- TMEM185B | c.612C>T p.A204= | Silent (SNP) | VAF 116/242 reads (48%) | catalogued as rs367892369, COSV101446832; called by muse, mutect2, varscan2
- ZBTB12 | c.786G>T p.V262= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- ZNF324B | c.1275C>T p.F425= | Silent (SNP) | VAF 155/490 reads (32%) | catalogued as rs1270835281; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848405 C>A | 5'Flank (SNP) | VAF 22/22 reads (100%) | called by muse, mutect2, varscan2
- ALOX12P2 | n.441G>T | RNA (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- ATP2B4 | c.3309+5761T>C | Intron (SNP) | VAF 61/156 reads (39%) | catalogued as rs911903457; called by muse, mutect2, varscan2
- CA12 | c.*2036C>G | 3'UTR (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2, varscan2
- CDK19 | c.*3132C>T | 3'UTR (SNP) | VAF 46/114 reads (40%) | called by muse, varscan2
- COL12A1 | c.*2129A>T | 3'UTR (SNP) | VAF 48/127 reads (38%) | called by muse, mutect2, varscan2
- COL3A1 | c.*515A>C | 3'UTR (SNP) | VAF 54/96 reads (56%) | called by muse, mutect2, varscan2
- ETS1 | chr11:128460097 C>A | 3'Flank (SNP) | VAF 6/15 reads (40%) | catalogued as rs11221316; called by muse, varscan2
- EXTL1 | c.*1098C>T | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2
- FNDC3B | c.*232A>C | 3'UTR (SNP) | VAF 47/87 reads (54%) | called by muse, mutect2, varscan2
- FZD4 | c.*930G>A | 3'UTR (SNP) | VAF 55/116 reads (47%) | catalogued as rs966619488; called by muse, mutect2, varscan2
- GABRB2 | c.*1899G>A | 3'UTR (SNP) | VAF 103/164 reads (63%) | called by muse, mutect2, varscan2
- GBA3 | c.*122T>G | 3'UTR (SNP) | VAF 58/130 reads (45%) | called by mutect2, varscan2
- HTR2B | c.*275G>T | 3'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- IGFN1 | c.1241+592G>A | Intron (SNP) | VAF 172/551 reads (31%) | called by muse, mutect2, varscan2
- IGHD3-3 | chr14:105918413 A>G | 5'Flank (SNP) | VAF 36/41 reads (88%) | called by muse, mutect2, varscan2
- IGHD3-3 | chr14:105918587 T>C | 5'Flank (SNP) | VAF 10/11 reads (91%) | called by muse, mutect2, varscan2
- IGHD3-3 | chr14:105918803 C>T | 5'Flank (SNP) | VAF 47/53 reads (89%) | catalogued as rs3829450; called by muse, mutect2, varscan2
- IGSF11 | c.*1711G>T | 3'UTR (SNP) | VAF 65/132 reads (49%) | called by muse, mutect2, varscan2
- KCNIP4 | c.61+98811del | Intron (DEL) | VAF 40/144 reads (28%) | called by pindel, varscan2*
- KIAA1671 | c.*2114C>A | 3'UTR (SNP) | VAF 38/94 reads (40%) | called by muse, mutect2, varscan2
- MAT2A | c.-8A>G | 5'UTR (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- NRK | c.*315G>A | 3'UTR (SNP) | VAF 89/95 reads (94%) | catalogued as rs1055041926; called by muse, mutect2, varscan2
- PCSK2 | c.-20C>A | 5'UTR (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- PRDX1 | c.-293T>G | 5'UTR (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- PRPF6 | chr20:64034573 G>T | 3'Flank (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- RBM12 | c.*28A>T | 3'UTR (SNP) | VAF 57/132 reads (43%) | called by muse, mutect2, varscan2
- RBMS3 | c.*977T>C | 3'UTR (SNP) | VAF 53/98 reads (54%) | called by muse, mutect2, varscan2
- RHBDL3 | c.*2513C>T | 3'UTR (SNP) | VAF 83/188 reads (44%) | called by muse, mutect2, varscan2
- SMIM30 | c.-124+32T>G | Intron (SNP) | VAF 112/185 reads (61%) | called by muse, mutect2, varscan2
- TNFAIP8 | c.*1158C>A | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2
- TNFSF4 | c.*933G>A | 3'UTR (SNP) | VAF 207/323 reads (64%) | catalogued as rs1407185992; called by muse, mutect2, varscan2
- URB1 | c.*2236_*2239del | 3'UTR (DEL) | VAF 53/166 reads (32%) | called by mutect2, pindel, varscan2
- VAT1L | c.*1229C>T | 3'UTR (SNP) | VAF 119/143 reads (83%) | catalogued as rs183655213; called by muse, mutect2, varscan2
- ZBED1 | chrX:2487623 G>T | 3'Flank (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
